Somatic mutation profile of tumor specimen TCGA-BJ-A4O8-01A (aliquot TCGA-BJ-A4O8-01A-11D-A257-08) from TCGA case TCGA-BJ-A4O8, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 47.7 years (17,430 days).
Specimen TCGA-BJ-A4O8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f31f038d-9e74-405f-a5e0-933a56536889.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A4O8-10A (Blood Derived Normal), aliquot TCGA-BJ-A4O8-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d273af32-93a1-441a-bad4-05cd8231bd41

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- RPL36AL | c.97T>G p.L33V | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV53564435; called by muse, mutect2, varscan2
- TP73-AS1 | n.1273C>T | RNA (SNP) | VAF 10/116 reads (9%) | catalogued as rs756755894; called by muse, mutect2
